Somatic mutation profile of tumor specimen CPT008928 (aliquot CPT008928-0002) from CPTAC case 01BR020, project CPTAC-2 (Breast). Tissue or organ of origin: Breast, NOS.
Specimen CPT008928: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0248f961-7484-4fe7-83cb-72af21633e26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT008542 (Blood Derived Normal), aliquot CPT008542-0001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e19c0be7-b7bd-4811-a5cf-114434c9bdd9

The open-access MAF lists 104 somatic variants for this specimen: 83 protein-altering or splice-affecting, 9 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Frame Shift Ins 20, Frame Shift Del 14, Silent 9, Intron 5, In Frame Ins 5, 3'UTR 3, In Frame Del 3, Nonsense Mutation 3, RNA 2, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 350/537 reads (65%) | catalogued as rs587781845, COSV52671445, COSV52701260, COSV52703282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS17 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 195/693 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs148578396; called by muse, mutect2, varscan2
- ADGRG1 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 85/406 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as rs377590979; called by muse, mutect2, varscan2
- BCLAF3 | c.1400C>A p.P467H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV61414167; called by muse, mutect2, varscan2
- CFAP57 | c.3464G>A p.R1155Q (on ENST00000372492 / NM_001378189.1; = p.R1188Q on NM_001195831.3) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs188867195; called by muse, mutect2, varscan2
- CGREF1 | c.832G>A p.E278K (on ENST00000260595; = p.E295K on NM_006569.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as rs113233839; called by muse, mutect2, varscan2
- DDX23 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as rs1306994953; called by muse, mutect2, varscan2
- DMD | c.3029C>A p.A1010E | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs780896933; called by muse, mutect2, varscan2
- GABRQ | c.989T>A p.I330N | Missense Mutation (SNP) | VAF 104/441 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100941080; called by muse, mutect2, varscan2
- MUC5B | c.16396G>C p.V5466L | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs372417271; called by muse, mutect2, varscan2
- NRXN1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.89); catalogued as rs1314011682, COSV68014715; called by muse, mutect2, varscan2
- NTRK3 | c.1954G>A p.G652R | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.319); catalogued as COSV62303179; called by muse, mutect2, varscan2
- P2RY4 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 74/428 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1021647336; called by muse, mutect2, varscan2
- POLR3E | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 36/285 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.131); catalogued as rs1406747422; called by muse, mutect2, varscan2
- PTCH2 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 175/588 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs779863570, COSV64710447; called by muse, mutect2, varscan2
- RNF223 | c.392G>C p.R131P | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs368270701; called by muse, mutect2, varscan2
- SEC16A | c.686G>C p.R229P | Missense Mutation (SNP) | VAF 72/268 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs751016125; called by muse, mutect2, varscan2
- SLC26A7 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.435); catalogued as rs142703308; called by muse, mutect2, varscan2
- SLC35A3 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1176953471, COSV64515773; called by mutect2, varscan2
- SNX20 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.375); catalogued as rs889072534; called by muse, mutect2, varscan2
- TMC2 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs941360826, COSV62656279; called by muse, mutect2, varscan2
- TRBV19 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1345095665; called by muse, mutect2
- ABCB5 | c.2227G>A p.G743S (on ENST00000404938 / NM_001163941.2; = p.G298S on NM_178559.6) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ACP7 | c.1181A>C p.E394A | Missense Mutation (SNP) | VAF 44/1110 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.295); called by muse, mutect2
- ADAMTS7 | c.1693_1695dup p.C565dup | In Frame Ins (INS) | VAF 40/146 reads (27%) | called by mutect2, pindel, varscan2
- AGRN | c.4130del p.F1377Sfs*50 | Frame Shift Del (DEL) | VAF 20/107 reads (19%) | called by mutect2, pindel, varscan2
- APOB | c.3122G>T p.G1041V | Missense Mutation (SNP) | VAF 68/539 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARHGDIA | c.302_303insA p.F102Vfs*18 | Frame Shift Ins (INS) | VAF 98/711 reads (14%) | called by mutect2, pindel, varscan2
- B4GALT2 | c.29_32dup p.V12Afs*23 | Frame Shift Ins (INS) | VAF 63/235 reads (27%) | called by mutect2, pindel, varscan2
- BCL11B | c.2636_2643dup p.L882Sfs*4 (on ENST00000357195 / NM_001282237.2; = p.L811Sfs*4 on NM_022898.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 100/672 reads (15%) | called by mutect2, varscan2
- C15orf39 | c.2372G>T p.R791L | Missense Mutation (SNP) | VAF 142/688 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.882); called by mutect2, varscan2
- CDT1 | c.1555_1560dup p.T519_Y520dup | In Frame Ins (INS) | VAF 79/549 reads (14%) | called by mutect2, varscan2
- CHRM1 | c.373_378delinsGGAG p.F125Gfs*124 | Frame Shift Del (DEL) | VAF 73/295 reads (25%) | called by pindel, varscan2*
- CNP | c.778_788dup p.A265Rfs*14 | Frame Shift Ins (INS) | VAF 51/141 reads (36%) | called by mutect2, pindel, varscan2
- CNP | c.998_1023del p.L333Rfs*6 | Frame Shift Del (DEL) | VAF 62/260 reads (24%) | called by mutect2, pindel, varscan2
- CTBP2 | c.370_394del p.C124Kfs*127 | Frame Shift Del (DEL) | VAF 107/477 reads (22%) | called by mutect2, pindel, varscan2
- DENND4C | c.5874_5875del p.*1959Nfs*8 (on ENST00000434457 / NM_001330640.2; = p.*1910Nfs*8 on NM_017925.7) | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- DYNC2H1 | c.6739G>T p.E2247* | Nonsense Mutation (SNP) | VAF 69/292 reads (24%) | called by muse, mutect2, varscan2
- EMILIN2 | c.3036_3043dup p.K1015Sfs*3 | Frame Shift Ins (INS) | VAF 56/340 reads (16%) | called by mutect2, varscan2
- ENTPD6 | c.192_199dup p.A67Gfs*67 | Frame Shift Ins (INS) | VAF 40/187 reads (21%) | called by mutect2, varscan2
- FAM120A | c.1804del p.Y602Ifs*39 | Frame Shift Del (DEL) | VAF 66/250 reads (26%) | called by mutect2, pindel, varscan2
- FANCB | c.974T>G p.L325R | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- FBXW5 | c.486_491dup p.H163_N164insKH | In Frame Ins (INS) | VAF 202/636 reads (32%) | called by pindel, varscan2
- FYCO1 | c.1934_1941dup p.A648Ifs*40 | Frame Shift Ins (INS) | VAF 17/110 reads (15%) | called by mutect2, varscan2
- FZR1 | c.856_866del p.S286Rfs*90 | Frame Shift Del (DEL) | VAF 81/205 reads (40%) | called by mutect2, pindel, varscan2
- GET3 | c.563_567del p.G188Afs*51 | Frame Shift Del (DEL) | VAF 82/258 reads (32%) | called by mutect2, pindel, varscan2
- GRIK2 | c.786dup p.A263Cfs*3 | Frame Shift Ins (INS) | VAF 32/89 reads (36%) | called by mutect2, pindel, varscan2
- HSD11B1L | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 76/102 reads (75%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPK1 | c.768_771dup p.S258Afs*39 | Frame Shift Ins (INS) | VAF 60/168 reads (36%) | called by mutect2, pindel, varscan2
- KRT8 | c.1342_1361dup p.T455Afs*16 | Frame Shift Ins (INS) | VAF 34/162 reads (21%) | called by mutect2, varscan2
- LCOR | c.1082_1091del p.V361Efs*3 | Frame Shift Del (DEL) | VAF 100/269 reads (37%) | called by mutect2, pindel, varscan2
- LTO1 | c.463C>A p.R155S | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.234); called by mutect2, varscan2
- MYBPC2 | c.295_299delinsT p.K99Lfs*66 | Frame Shift Del (DEL) | VAF 88/382 reads (23%) | called by pindel, varscan2*
- NEB | c.14631dup p.K4878Qfs*3 | Frame Shift Ins (INS) | VAF 21/127 reads (17%) | called by mutect2, pindel, varscan2
- NFE2L1 | c.1425dup p.D476* | Frame Shift Ins (INS) | VAF 100/333 reads (30%) | called by mutect2, pindel, varscan2
- NOC2L | c.1702C>G p.R568G | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- NUP160 | c.3405_3417dup p.A1140Sfs*17 | Frame Shift Ins (INS) | VAF 30/73 reads (41%) | called by mutect2, varscan2
- PCNX3 | c.4262_4264del p.V1421del | In Frame Del (DEL) | VAF 140/492 reads (28%) | called by mutect2, pindel, varscan2
- PCOLCE | c.693G>T p.R231S | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- PHC1 | c.2576_2577dup p.R860Afs*46 | Frame Shift Ins (INS) | VAF 25/174 reads (14%) | called by mutect2, pindel, varscan2
- PHLDB1 | c.3301C>T p.R1101C | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PLEKHM2 | c.2233_2234del p.Y745Rfs*151 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | called by mutect2, pindel, varscan2
- PPP4R3C | c.2182A>T p.T728S | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.828); called by muse, mutect2
- PRPF40B | c.2021_2023del p.R674del (on ENST00000380281; = p.R661del on NM_012272.3) | In Frame Del (DEL) | VAF 44/280 reads (16%) | called by mutect2, pindel, varscan2
- R3HDM2 | c.2655_2663del p.L886_T888del | In Frame Del (DEL) | VAF 31/168 reads (18%) | called by mutect2, pindel, varscan2
- RBM8A | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 111/270 reads (41%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- RERE | c.1733_1737dup p.S580Gfs*52 | Frame Shift Ins (INS) | VAF 92/311 reads (30%) | called by mutect2, pindel, varscan2
- RNF38 | c.1298_1299insTTTGACTGGGAGAGGC p.K434Lfs*12 | Frame Shift Ins (INS) | VAF 10/58 reads (17%) | called by mutect2, varscan2
- SCRIB | c.3524_3530del p.Q1175Pfs*55 | Frame Shift Del (DEL) | VAF 58/448 reads (13%) | called by mutect2, pindel, varscan2
- SIPA1L1 | c.4860_4869del p.L1622Rfs*4 | Frame Shift Del (DEL) | VAF 77/363 reads (21%) | called by mutect2, pindel, varscan2
- SLC20A1 | c.274G>C p.V92L | Missense Mutation (SNP) | VAF 66/712 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2
- SNAP25 | c.408G>C p.R136S | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- SRSF6 | c.602_606dup p.R203Efs*89 | Frame Shift Ins (INS) | VAF 24/260 reads (9%) | called by mutect2, pindel
- ST13 | c.773_793dup p.R258_A264dup | In Frame Ins (INS) | VAF 6/28 reads (21%) | called by pindel, varscan2
- STRN4 | c.1247_1248+1dup p.X416_splice | Splice Site (INS) | VAF 69/192 reads (36%) | called by mutect2, pindel, varscan2
- TEX2 | c.3128_3135dup p.V1046Lfs*16 (on ENST00000583097 / NM_001288733.2; = p.V1053Lfs*16 on NM_018469.5) | Frame Shift Ins (INS) | VAF 21/132 reads (16%) | called by mutect2, varscan2
- TMEM131L | c.2103del p.S702Hfs*4 | Frame Shift Del (DEL) | VAF 109/233 reads (47%) | called by mutect2, pindel, varscan2
- TNRC18 | c.7595_7599dup p.T2534Gfs*269 | Frame Shift Ins (INS) | VAF 40/248 reads (16%) | called by mutect2, pindel, varscan2
- TNRC18 | c.7438G>A p.A2480T | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- TTC4 | c.914T>A p.M305K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USP36 | c.2656A>T p.R886* | Nonsense Mutation (SNP) | VAF 378/445 reads (85%) | called by muse, mutect2, varscan2
- WIZ | c.1419_1421dup p.P474dup | In Frame Ins (INS) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- WNT7B | c.221_231dup p.R78Sfs*26 | Frame Shift Ins (INS) | VAF 100/364 reads (27%) | called by mutect2, varscan2
- ANGPTL1 | c.1389G>A p.K463= | Silent (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
- CA5A | c.444C>T p.H148= | Silent (SNP) | VAF 87/166 reads (52%) | catalogued as rs575569678; called by muse, mutect2, varscan2
- COL14A1 | c.2484A>G p.P828= | Silent (SNP) | VAF 97/182 reads (53%) | called by muse, mutect2, varscan2
- KCNG2 | c.537C>T p.F179= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as rs765638471, COSV60267089; called by muse, mutect2, varscan2
- NHLH1 | c.379C>T p.L127= | Silent (SNP) | VAF 21/157 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.25818C>T p.T8606= (on ENST00000591111; = p.T7679= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs373578441; called by muse, mutect2
- UCKL1 | c.1539T>C p.N513= | Silent (SNP) | VAF 251/514 reads (49%) | called by muse, mutect2, varscan2
- WWC3 | c.2049G>A p.L683= | Silent (SNP) | VAF 93/265 reads (35%) | called by muse, mutect2, varscan2
- ZCCHC14 | c.945C>A p.P315= (on ENST00000268616; = p.P452= on NM_015144.3) | Silent (SNP) | VAF 54/122 reads (44%) | catalogued as rs749642902, COSV51888112; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+3210T>C | Intron (SNP) | VAF 32/215 reads (15%) | called by muse, mutect2, varscan2
- CCER1 | chr12:90947821 T>G | 3'Flank (SNP) | VAF 58/225 reads (26%) | called by muse, mutect2, varscan2
- DOCK8 | c.1797+95G>A | Intron (SNP) | VAF 74/219 reads (34%) | catalogued as rs759876037; called by muse, mutect2, varscan2
- ERICH4 | c.-11G>T | 5'UTR (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- GORAB | c.*533C>T | 3'UTR (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- H2BC18 | c.378-9437C>G | Intron (SNP) | VAF 70/448 reads (16%) | called by muse, mutect2, varscan2
- LINC01956 | n.353C>T | RNA (SNP) | VAF 49/247 reads (20%) | called by muse, mutect2, varscan2
- MZF1 | c.-41+462C>A | Intron (SNP) | VAF 22/166 reads (13%) | called by mutect2, varscan2
- SIRPB1 | c.76+15075C>G | Intron (SNP) | VAF 231/641 reads (36%) | called by muse, mutect2, varscan2
- UQCRB | c.*2948_*2962del | 3'UTR (DEL) | VAF 131/505 reads (26%) | called by mutect2, pindel, varscan2
- UXT | c.*7C>A | 3'UTR (SNP) | VAF 37/148 reads (25%) | called by muse, mutect2, varscan2
- XIST | n.7317C>T | RNA (SNP) | VAF 58/264 reads (22%) | catalogued as rs768608990; called by muse, mutect2, varscan2
